Somatic mutation profile of tumor specimen MP2PRT-PATTLH-TMP1-A (aliquot MP2PRT-PATTLH-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATTLH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,319 days).
Specimen MP2PRT-PATTLH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efa6343d-b01f-47d2-84ee-8f99912222a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATTLH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATTLH-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9129f58e-9099-482a-aedd-bda8e21b3604

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B3 | c.3322G>A p.A1108T | Missense Mutation (SNP) | VAF 163/485 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as rs764851413, COSV59544240; called by muse, mutect2, varscan2
- DNAH7 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 15/245 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.09); catalogued as rs766889410, COSV56765144; called by muse, mutect2
- LRP1B | c.2995G>T p.E999* | Nonsense Mutation (SNP) | VAF 18/420 reads (4%) | catalogued as COSV67188041; called by muse, mutect2
- MLH3 | c.3640G>A p.A1214T | Missense Mutation (SNP) | VAF 86/251 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV99470030; called by muse, mutect2, varscan2
- NUP210L | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 96/270 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs745416091, COSV55141814; called by muse, mutect2, varscan2
- SERTAD1 | c.530T>C p.I177T | Missense Mutation (SNP) | VAF 114/556 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1014025191; called by muse, mutect2
- TAS2R16 | c.451C>G p.Q151E | Missense Mutation (SNP) | VAF 102/323 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.08); catalogued as rs765921681, COSV50796821; called by muse, mutect2, varscan2
- CACNG4 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 30/744 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.169); called by muse, mutect2
- DMBT1 | c.6266C>G p.S2089C (on ENST00000338354 / NM_001377530.1; = p.S1332C on NM_004406.3) | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- EPPK1 | c.3658G>C p.E1220Q | Missense Mutation (SNP) | VAF 27/727 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.118); called by muse, mutect2
- FBXO33 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 84/733 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GIPC3 | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 85/698 reads (12%) | called by muse, varscan2
- IGHV4-59 | chr14:106627248 GTCT>CCGGTGGCTCCTGGAAACCCCCA | Missense Mutation (INS) | VAF 44/188 reads (23%) | called by pindel, varscan2*
- NR4A1 | c.734T>C p.I245T | Missense Mutation (SNP) | VAF 31/711 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- NXPH2 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 17/508 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.536); called by muse, mutect2
- PIWIL1 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 55/566 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC7A2 | c.1865C>T p.P622L (on ENST00000494857 / NM_001370338.1; = p.P661L on NM_003046.6) | Missense Mutation (SNP) | VAF 12/383 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- UBA5 | c.159_160dup p.S54Tfs*4 | Frame Shift Ins (INS) | VAF 115/422 reads (27%) | called by mutect2, pindel, varscan2
- PITPNM2 | c.2160C>T p.T720= | Silent (SNP) | VAF 155/486 reads (32%) | catalogued as rs776390647; called by muse, mutect2, varscan2
- SELENOV | c.390C>G p.L130= | Silent (SNP) | VAF 289/778 reads (37%) | called by muse, mutect2, varscan2
- SERPINC1 | c.993C>A p.L331= | Silent (SNP) | VAF 39/670 reads (6%) | called by muse, mutect2
- ZFHX3 | c.2124G>A p.Q708= | Silent (SNP) | VAF 154/463 reads (33%) | catalogued as rs368860649; called by muse, mutect2, varscan2
- THBS3 | c.1548+36C>A | Intron (SNP) | VAF 16/550 reads (3%) | called by muse, mutect2
